Surgical pathology report (de-identified scan), TCGA case TCGA-LN-A49Y, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ILSBIO, specimen TCGA-LN-A49Y-01A (Primary Tumor).

[page 1 of 5]
Tel:

Fax:

Clinical Case Report **(For Collection of Cancerous Tissue)**

1CD-0-3

Carcinoma, squamous cell, NOS 8070/3

Site: esophagus, middle third C15.4

for 10/2/12

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Long 68	☐ Single ☒ Married	VIETNAMESE	
☒ Male ☐ Female	Weight 57kg	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
			12/8	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Fever; Trouble Swallowing
Symptoms: weight loss
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☒ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses	# of Pregnancies
	Date of Last Menses	# of Live Births
	Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____	
		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		2 drinks/day	(yrs)	1 yr ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers:					

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy	carcinoma	

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T3 N0 M0 Stage: IIA	

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Resection of esophagus			
Primary Tumor			
Organ	Detailed Location	Size	
esophagus tumor	middle	1 x 0.8 x cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T3 N0 M0 Stage: IIA			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: ____

____ Date:

Time: _

Preserved by: ____

____ Date:

Time: _

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
2	2	2	2			2	2
Time to LN2		Time to Formalin		Time to LN2			
10 min		11 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
esophagus Tumor	1 x 0.8 x cm	middle	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₃ N ₀ M ₀		Stage: IIA	
Notes:			

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		STRUCTURAL PATTERN	
	+ -		+ -
Diffuse		Streaming	
Mosaic		Storiform	
Necrosis		Fibrosis	
Lymphocytic Infiltration		Palisading	
Vascular Invasion		Cystic Degeneration	
Clusterized		Bleeding	
Alveolar Formation		Myxoid Change	
Indian File		Psamomma/Calcification	

2. Cellular features:

Squamous	+ -	Adenomatous	+ -	Sarcomatous	+ -	Lymphomatous	+ -
Squamoid Cell		Glandular cell		Round Cell		Large Cell	
Spindle Cell		Cell Stratification		Fibroblast		Small Cell	
Keratin		Secretion		Osteoblast		RS Cell/RS Like	
Desmosome		Intracyt. Vacuole		Lipoblast		Inflam. Cell	
Pearl		Gland formation		Myoblast		Plasma Cell	
Otherwise Specified: D. 80%, M. 50%							

2. Cellular Differentiation:

Well	Moderately	Poor
	X	

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				
Hyperchromatism				
Nucleolar Prominent				
Multinucleated Giant Cell				
Mitotic Activity				
Nuclear Grade				

Histological Diagnosis: Squamous Cell Carcinoma, G-2

Comments: _____

Date

Director, Research Pathology

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

H/AA Discrepancy		X

Source: NCI Genomic Data Commons file dad4b27a-2546-4139-a0d7-11e8e24e5b69 (TCGA-LN-A49Y.32800FA9-9865-4E4C-9B2C-010849E32CD8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).